Gene-level copy-number profile of tumor specimen TCGA-13-0923-01A from TCGA case TCGA-13-0923, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.1 years (27,081 days).
Specimen TCGA-13-0923-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ea9edd51-f159-4f8d-8d59-3a6256dd4e33.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0923-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/41b2451a-6d9e-4638-ab8f-e4569d4a2da9

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,869; copy number 2: 17,791; copy number 3: 24,092; copy number 4: 9,372; copy number 5: 4,305; copy number 6: 1,183; copy number 7: 32; copy number 8: 137; copy number 9: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0923-01A-01D-0399-01): tumor purity 0.78, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 202 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:63,719,980–65,707,226, 1 gene, copy number 7 (within-gene range 4–7): EYS.
- chr6:64,377,795–70,212,468, 31 genes, copy number 7: AL357375.1, HNRNPDP2, AL355357.1, AL365217.1, SLC25A51P1, ADH5P4, NUFIP1P1, AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA, AL713998.1, AL713998.3, AL713998.4, AL713998.2, AL646090.2, AL646090.1, AL593844.1, LINC02549, AL606923.2, AL606923.1, AL391807.1, ADGRB3, LMBRD1, NPM1P37, GAPDHP42, COL19A1, RPL37P15.
- chr12:25,409,307–25,648,579, 1 gene, copy number 8 (within-gene range 6–8): LMNTD1.
- chr12:25,585,994–32,993,754, 169 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,781. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
